Gene-level copy-number profile of tumor specimen TCGA-XF-A9SY-01A from TCGA case TCGA-XF-A9SY, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 60.8 years (22,212 days).
Specimen TCGA-XF-A9SY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.d163ef9b-966b-4031-89fb-09ff04e1d7a4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-A9SY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f8f81d46-d1e2-4a22-8d9e-01f83308c9a1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 28,218; copy number 3: 25,131; copy number 4: 4,387; copy number 5: 1,112; copy number 6: 746; copy number 7: 12; copy number 8: 73; copy number 9: 60; copy number 10: 15; copy number 11: 13; copy number 12: 39; copy number 14: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-A9SY-01A-21D-A42D-01): tumor purity 0.18, ploidy 2.76, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,077 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:107,249,482–109,975,771, 31 genes, copy number 9–14 (within-gene range 3–14): ANGPT1, AC091010.1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, U2, AC023245.1, KCNV1, AC027451.1.
- chr8:113,600,310–125,367,120, 147 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).
- chr8:125,859,721–126,292,788, 1 gene, copy number 12 (within-gene range 4–12): LINC00861.
- chr8:125,998,994–128,220,803, 38 genes, copy number 12: AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226.
- chr8:129,839,593–130,655,712, 15 genes, copy number 10 (within-gene range 4–10): CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1.
- chr8:131,712,512–133,571,940, 26 genes, copy number 9 (within-gene range 4–9): AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3.
- chr8:137,424,904–137,425,021, 1 gene, copy number 7: ZYXP1.
- chr9:14,475–26,118,408, 348 genes, copy number 6 (broad region; genes not listed).
- chr11:167,784–46,929,320, 1,048 genes, copy number 5 (broad region; genes not listed).
- chr15:97,215,812–98,547,728, 26 genes, copy number 6: LINC02253, AC020704.1, LINC02254, RN7SL677P, RNA5SP401, AC026523.2, AC026523.1, AC026523.3, AC026523.4, LINC00923, AC024651.2, AC024651.3, ARRDC4, AC024651.1, LINC02251, U6, AC022523.1, RNU6-1186P, LINC01582, AC022523.3, AC022523.2, AC015722.1, AC015722.2, LINC02351, FAM169B, AC103968.1.
- chr17:46,833,201–47,746,122, 31 genes, copy number 6: WNT9B, LINC01974, AC005670.1, RNU6ATAC3P, GOSR2, AC005670.2, MIR5089, RPRML, LRRC37A17P, AC005670.3, RN7SL270P, CDC27, AC002558.1, AC002558.3, AC002558.2, MYL4, ITGB3, AC068234.1, RNU7-186P, AC068234.2, THCAT158, EFCAB13, AC040934.1, MRPL45P2, NPEPPS, Y_RNA, AC025682.1, KPNB1, AC015674.1, TBKBP1, TBX21.
- chr19:28,294,093–36,605,276, 278 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr22:19,520,572–21,081,018, 87 genes, copy number 5–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
